Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3YD, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3YD-01A (Primary Tumor).

[page 1 of 2]
**SurgPath Final
Temporary Copy**

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Page 1 of 2

Patient: [REDACTED]
ID: [REDACTED]
Location: [REDACTED]

FINAL DIAGNOSIS

- A) Right thyroid lobe and isthmus: Papillary thyroid carcinoma (1.5 x 1.0 x 0.8 cm) with fibrosis and surrounding adenomatous thyroid hyperplasia. Negative for definite lymphatic/vascular invasion. Surgical margins of resection free of tumor.
- B) Left thyroid lobe: Adenomatous hyperplasia without diagnostic evidence of neoplasm.
- C) Central compartment lymph nodes: Metastatic papillary thyroid carcinoma in two of six lymph nodes (2/6). Thymic epithelium is also identified.

Comment: Selective slides reviewed with Dr. [REDACTED]

[REDACTED]
[REDACTED]

[REDACTED]
[REDACTED]

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

6-7-12

RD

SPECIMEN RECEIVED

- A) RIGHT THYROID LOBE AND ISTHMUS, F/S
B) LEFT THYROID LOBE
C) CENTRAL COMPARTMENT LYMPH NODES

FROZEN SECTION

- A) Right thyroid lobe and isthmus: Papillary thyroid carcinoma.

GROSS DESCRIPTION

A) Received fresh for frozen section labeled "right thyroid lobe and isthmus" is a lobe of thyroid weighing 18 grams and measuring 5.0 x 3.5 x 2.8 cm. The red/tan capsular surface appears intact. The specimen is inked on its surgical margins with black ink, serially sectioned and reveals a 1.5 x 1.0 x 0.8 cm white/tan indurated focally calcified lesion, which grossly comes to within approximately 0.3 cm of the inked capsular margin. Touch preps are made from the lesion and a representative portion is submitted for frozen section as A1. The remainder of the thyroid displays beefy red/tan thyroid parenchyma. No additional lesions are identified. A portion of mass is submitted for the 7 Additional sections are submitted for permanent section as follows: A2 and A3 remainder of mass, A4 through A7 sections of thyroid.

[page 2 of 2]
**SurgPath Final
Temporary Copy**

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Page 2 of 2

Patient: [REDACTED]
ID: [REDACTED]

B) Received fresh labeled "left thyroid lobe" is a lobe of thyroid weighing 13 grams and measuring 5.5 x 3.0 x 1.5 cm. The red/tan capsule appears intact. The specimen is inked on its surgical margins with black ink, serially sectioned and reveals a 0.8 cm yellow/tan nodule in the mid portion of the specimen. This nodule focally abuts the inked capsule. The remainder of the thyroid displays beefy red/tan thyroid parenchyma. Representative sections are submitted as follows: B1 entirely submitted bisected nodule, B2 through B6 additional sections of thyroid.

C) Received in formalin labeled "central compartment lymph node" is an ovoid portion of yellow lobulated adipose tissue measuring 3.5 x 2.5 x 0.4 cm. Dissection yields multiple small embedded lymph nodes measuring up to 0.3 cm in greatest dimension. The specimen is entirely submitted in C1-C2.

CLINICAL INFORMATION
THYROID MASS

IHPAA Discrepancy		
Tumor Malignancy History		

Source: NCI Genomic Data Commons file 170e6ad3-1346-4d4f-bff3-25b09dbe571b (TCGA-J8-A3YD.8D2F7D6B-AF3B-4F61-91DD-8C84A3A2B0AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).